Gene-level copy-number profile of tumor specimen ALCH-B2FP-TTP1-A from ALCHEMIST case ALCH-B2FP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.2 years (25,658 days).
Specimen ALCH-B2FP-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 06f69154-32ea-40fe-a439-20c24dfaa108.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2FP-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/fe2fe40b-62e1-4cc1-ae4d-e64b14073146

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 45; copy number 1: 8,994; copy number 2: 46,442; copy number 3: 2,253; copy number 4: 615; copy number 5: 5; copy number 6: 43; copy number 9: 1.

Homozygous deletions (total copy number 0; autosomes only): 45 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:3,156,756–3,157,797, 1 gene: AC019118.1.
- chr3:3,981,981–3,984,295, 1 gene (within-gene range 0–1): PNPT1P1.
- chr9:128,411,751–128,437,351, 2 genes: CERCAM, AL359091.4.
- chr10:42,149,310–42,149,549, 1 gene: KSR1P1.
- chr15:25,169,337–25,225,284, 31 genes (within-gene range 0–1): DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30.
- chr15:84,398,316–84,411,701, 2 genes: DNM1P51, CSPG4P5.
- chr15:93,035,273–93,089,204, 2 genes: RGMA, YBX2P2.
- chr19:58,573,503–58,605,223, 4 genes (within-gene range 0–2): CENPBD1P1, AC016629.3, AC016629.1, AC016629.2.
- chr21:44,347,767–44,348,295, 1 gene: AP001063.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 49 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:42,155,406–42,217,861, 5 genes, copy number 5: AL096814.1, AL096814.2, GUCA1A, GUCA1B, MRPS10.
- chr7:54,419,444–56,000,181, 42 genes, copy number 6: SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3, AC092647.1, AC092647.2, AC092647.5, ZNF713, NIPSNAP2, MRPS17.
- chr15:84,235,773–84,245,368, 1 gene, copy number 9: GOLGA6L4.
- chr22:21,141,624–21,142,371, 1 gene, copy number 6: E2F6P2.

Autosomal genes at a single copy (total copy number 1): 8,994. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
